Surgical pathology report (de-identified scan), TCGA case TCGA-G8-6907, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Roswell Park, specimen TCGA-G8-6907-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

NODES LEFT CERVICAL NECK

FINAL DIAGNOSIS:

LYMPH NODE, left CERVICAL NECK, excision:
MALIGNANT LYMPHOMA, DIFFUSE, LARGE CELL TYPE (IWF G1).

DIAGNOSIS COMMENT:

Note: see flow cytometry immunophenotypic report.

GROSS DESCRIPTION:

NODES LEFT CERVICAL NECK

Received in formalin is an irregular lymph node measuring
1x0.5x0.7 cm. Tissue has been submitted for tissue procurement and
flow cytometry. The remainder is submitted in B5 or formalin.

Date of surgery:

[page 2 of 2]
SPECIMENS:

BM BX RA
BM BX LA

FINAL DIAGNOSIS:

BONE MARROW, right and left iliac crest biopsies, sections,
imprints and smears:
-ORDERLY HEMOPOIESIS
-Negative for lymphoma

DIAGNOSIS COMMENT:

[BBone Marrow 1: Asp & Bx (No cytochem)]b

Pt. Data: Hgb 13.2 WBC 9.65 Plat. 322.0

I. [UAspirate - Differential[u(%): Rt touch prep

Cells Counted 500 Cellularity estimate 2+ M:E 2.8/1

Megakaryocytes: Dysplasia: Grade 0 Quantity: Normal

[UMyeloid cells Monos/Lymphs]u [UErythroid cells/Other]u
Dysplasia Grade 0 Dysplasia Grade 0

2.0 myeloblasts NG monoblasts 0.2 pronorm.
4.4 promyelocytes NG promonocytes 25.0 normoblasts
12.2 myelocytes 0.4 monocytes NG sideroblasts *
10.4 metamyelocytes 3.6 lymphocytes NG ring siderobl.**
22.2 bands/stabs NG lymphoblasts 0.2 plasma cells
17.2 segs NG abnormal lymphs 0.2 histiocytes
2.0 eosinophilic NG unclass. blasts NG other _____
0.2 basophilic 71.0 TOTAL myeloid & mono

*: as % of normoblasts; **: as % of all nucleated cells

Comment on Diff: History of lymphoma. Orderly hemopoiesis.

II.[U Biopsy data]u:

1. Cellularity: 50%
2. Myeloid/erythroid ratio: 3/1
3. Myeloid series: Dysplasia: Grade 0 Quantity: Normal
4. Erythroid series: Dysplasia: Grade 0 Quantity: Normal
5. Megakaryocytes: Dysplasia: Grade 0 Quantity: Normal
6. Iron stores: Not evaluable
7. Abnormal infiltrate: None
8. Other:
9. Comparison to Previous Bx: N/A

GROSS DESCRIPTION:

1. BM BX RA

Received in B5 and 37% formalin in bottle labeled with patient name and labeled bone marrow biopsy right is a brown-tan core of bone measuring 0.5 cm. in length. Submitted in toto.

2. BM BX LA

Received in B5 and 37% formalin in bottle labeled with patient name labeled bone marrow biopsy left are three brown-tan fragments of core of bone measuring in aggregate length 0.7 cm. Submitted in toto.

Source: NCI Genomic Data Commons file a3e0f64a-f436-4609-ad63-4f3f6148348f (TCGA-G8-6907.47B6EB78-0DCF-4105-8CCA-1835ECF8033D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).